Somatic mutation profile of tumor specimen TCGA-DX-A3U5-01A (aliquot TCGA-DX-A3U5-01A-11D-A228-09) from TCGA case TCGA-DX-A3U5, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 52.3 years (19,088 days).
Specimen TCGA-DX-A3U5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8aeb60c-75c3-471b-a072-3431c1ea12fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A3U5-10A (Blood Derived Normal), aliquot TCGA-DX-A3U5-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/800191de-5ad4-43d0-8fbf-7694f6c803ef

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 4, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.4076G>A p.C1359Y | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67132002; called by muse, mutect2, varscan2
- CEP131 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs530864094, COSV53953733; called by muse, mutect2, varscan2
- ITGA5 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs758635941; called by muse, varscan2
- NAV3 | c.3242G>A p.S1081N | Missense Mutation (SNP) | VAF 28/584 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV57110301; called by muse, mutect2
- PIK3CD | c.2592G>A p.P864= | Splice Region (SNP) | VAF 22/64 reads (34%) | catalogued as rs201426574; called by muse, mutect2, varscan2
- RAD50 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99528701; called by muse, mutect2, varscan2
- TOPBP1 | c.4102C>G p.R1368G | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.302); catalogued as COSV99605579; called by muse, mutect2
- TRBV27 | c.124T>A p.C42S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757731055; called by muse, mutect2, varscan2
- TSPAN8 | c.444G>C p.E148D | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.158); catalogued as COSV56078675; called by muse, mutect2
- UGT1A4 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs188914242; called by muse, mutect2, varscan2
- ACADL | c.804G>C p.L268F | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- CCT2 | c.443A>T p.H148L | Missense Mutation (SNP) | VAF 24/836 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.347); called by muse, mutect2
- CFAP54 | c.5822G>C p.W1941S | Missense Mutation (SNP) | VAF 20/483 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DMKN | c.1243G>C p.A415P | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MUC17 | c.7367C>A p.T2456N | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- MYO16 | c.1447C>A p.Q483K | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- NDN | c.905G>T p.R302I | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- OR13A1 | c.29T>G p.I10R | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB9 | c.1482G>C p.Q494H | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.012); called by muse, mutect2
- REEP3 | c.752C>G p.P251R | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- RLN1 | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- SLC38A5 | c.499T>A p.F167I | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- TRBV2 | c.112G>C p.V38L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.401); called by mutect2, varscan2
- CADPS | c.3054G>A p.V1018= | Silent (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- CYB5R4 | c.1467C>T p.L489= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as rs775121428, COSV63752306; called by muse, mutect2, varscan2
- CYP4F2 | c.75C>T p.V25= | Silent (SNP) | VAF 27/156 reads (17%) | catalogued as rs142765310; called by muse, mutect2, varscan2
- HEPHL1 | c.564G>A p.S188= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs375814141; called by muse, mutect2, varscan2
- KIR3DX1 | n.518G>C | RNA (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
